Somatic mutation profile of tumor specimen TCGA-A5-A3LP-01A (aliquot TCGA-A5-A3LP-01A-11D-A228-09) from TCGA case TCGA-A5-A3LP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.3 years (27,131 days).
Specimen TCGA-A5-A3LP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1167c00a-9d1d-4cd9-bb74-e79fe3a15288.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A3LP-10A (Blood Derived Normal), aliquot TCGA-A5-A3LP-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4f0f836-ada8-40c4-b5d0-80d09a7b00ff

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 13, Splice Site 2, Nonsense Mutation 1, RNA 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANGPT4 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1207288280, COSV101124592, COSV101124926; called by muse, mutect2, varscan2
- ANK3 | c.10646G>A p.R3549Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs776768218, COSV55054192, COSV55089177; called by muse, mutect2, varscan2
- ATAD2 | c.3728C>G p.S1243* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99785530; called by muse, mutect2, varscan2
- C17orf64 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV52256363, COSV99293722; called by muse, mutect2, varscan2
- CALR3 | c.92-1G>A p.X31_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as rs373161457; called by muse, mutect2, varscan2
- CHD1L | c.2048A>G p.Q683R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100787671; called by muse, mutect2, varscan2
- COL12A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.192); catalogued as rs779083996, COSV100486824, COSV59396626; called by muse, mutect2, varscan2
- COL5A2 | c.3805C>A p.H1269N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100880984; called by muse, mutect2, varscan2
- CPSF7 | c.1295G>A p.R432Q (on ENST00000394888 / NM_001136040.4; = p.R475Q on NM_024811.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs775930483, COSV100467717; called by muse, mutect2, varscan2
- CSF1 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs1405726512, COSV100294875; called by muse, mutect2, varscan2
- DENND1A | c.2566G>A p.G856R | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.851); catalogued as rs758039314, COSV101012398; called by muse, mutect2, varscan2
- DLAT | c.644A>C p.Y215S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99735114; called by muse, mutect2, varscan2
- DYNC1H1 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100795610; called by muse, mutect2, varscan2
- ERBB3 | c.655T>G p.F219V | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57246260, COSV99918190; called by muse, mutect2, varscan2
- FBXO4 | c.767A>T p.N256I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99715365; called by muse, mutect2, varscan2
- FLNB | c.2795G>A p.S932N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99915584; called by muse, mutect2, varscan2
- GUCY2F | c.2117C>G p.S706C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV99485902; called by muse, mutect2, varscan2
- HACL1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100329897; called by muse, mutect2, varscan2
- HADHA | c.200A>C p.E67A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV101024291, COSV66108451; called by muse, mutect2, varscan2
- HYOU1 | c.1106G>A p.S369N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101345708; called by muse, mutect2, varscan2
- ITGAM | c.2516G>A p.R839H (on ENST00000648685 / NM_001145808.2; = p.R838H on NM_000632.4) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1475357620, COSV54938709; called by muse, mutect2, varscan2
- LMNB2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.976); catalogued as COSV100322517; called by muse, mutect2, varscan2
- METTL7A | c.617G>C p.R206T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100153749; called by muse, mutect2, varscan2
- MTNR1B | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs762043101, COSV57065749, COSV99925430; called by muse, mutect2, varscan2
- NOTCH2 | c.4093C>T p.R1365C | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs987757552, COSV99867505; called by muse, mutect2, varscan2
- OR6B1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs374206359, COSV68769859; called by muse, mutect2, varscan2
- PCDHA12 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as COSV100255973; called by muse, mutect2, varscan2
- PCDHGA3 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99549609; called by muse, mutect2, varscan2
- PKP4 | c.1869G>T p.L623F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV101081776; called by muse, mutect2, varscan2
- PPP1R3B | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs567890001, COSV60100042; called by muse, mutect2, varscan2
- PTBP2 | c.1336C>T p.R446C (on ENST00000426398 / NM_001300986.2; = p.R438C on NM_021190.4) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100930303; called by muse, mutect2, varscan2
- RALGAPB | c.3509C>A p.P1170Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs1285723451, COSV99486017; called by muse, mutect2
- RPL3L | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145928459, COSV99238569; called by muse, mutect2, varscan2
- SLC26A7 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV99404630; called by muse, mutect2, varscan2
- SYNE1 | c.12065G>A p.S4022N (on ENST00000367255 / NM_182961.4; = p.S3951N on NM_033071.3) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99584271; called by muse, mutect2, varscan2
- UBQLN2 | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV100592849; called by muse, mutect2, varscan2
- UBR4 | c.4181G>A p.R1394H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs756549939, COSV64385199; called by muse, mutect2, varscan2
- DLG3 | c.1297_1302+11delinsAG p.X433_splice (on ENST00000374360 / NM_021120.4; = p.X96_splice on NM_020730.3) | Splice Site (DEL) | VAF 6/27 reads (22%) | called by pindel, varscan2*
- FOXA2 | c.404_405dup p.M136Pfs*8 (on ENST00000377115 / NM_153675.3; = p.M142Pfs*8 on NM_021784.5) | Frame Shift Ins (INS) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- MAP3K12 | c.2066del p.G689Efs*10 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- SYNGR2 | c.577_585del p.A193_Y195del | In Frame Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- AHNAK2 | c.5325G>A p.A1775= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs375331989; called by muse, mutect2, varscan2
- ASTN1 | c.1278C>T p.R426= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99923571; called by muse, mutect2, varscan2
- ATP9B | c.2271C>T p.N757= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs769680255, COSV56947426; called by muse, mutect2, varscan2
- CSNK1A1 | c.444T>G p.R148= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99939891; called by muse, mutect2, varscan2
- MACF1 | c.18012G>A p.E6004= (on ENST00000372915; = p.E4049= on NM_012090.5) | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99247606; called by muse, mutect2, varscan2
- MMP14 | c.561C>T p.G187= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as rs768586381, COSV61287884; called by muse, mutect2, varscan2
- MYBPH | c.1146C>T p.P382= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs1372631741, COSV99704851; called by muse, mutect2, varscan2
- PCDHA13 | c.183G>A p.P61= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV56493090; called by muse, mutect2, varscan2
- PCDHGB2 | c.1578C>T p.R526= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs747794210, COSV99533884; called by muse, mutect2, varscan2
- PIK3CA | c.1950G>C p.V650= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV99845442; called by muse, mutect2, varscan2
- SLC25A5 | c.507G>T p.G169= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100510524; called by muse, mutect2
- TNFAIP3 | c.1332G>A p.E444= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99397376; called by muse, varscan2
- ZNF37A | c.1347C>T p.C449= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100697506; called by muse, mutect2, varscan2
- ZNF658B | n.2503G>A | RNA (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
